Surgical pathology report (de-identified scan), TCGA case TCGA-ZF-A9R1, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Sheffield, specimen TCGA-ZF-A9R1-01A (Primary Tumor).

[page 1 of 3]
Reporting pathologist(s): CONSULTANT.

Sample (TYPE UNSPECIFIED) Collected

Received

HISTOLOGY

HISTOLOGY

SPECIMEN

- A - Bladder & prostate.
- B - Peri-bladder nodes.
- C - Right external iliac node.
- D - Right anterior obturator node.
- E - Right posterior obturator node.
- F - Left external iliac node.
- G - Left anterior obturator node.
- H - Left posterior obturator node.
- I - Left ureteric margin.
- J - Right ureteric margin.

ICD-O-3

Carcinoma, urothelial NOS 8/20/3

Site: Bladder NOS C67.9

5/2/14

CLINICAL DETAILS

Radical cystoprostatectomy for G3 pT2 TCC diagnosed at

Verified by TSS - pT2 on bx only -
pT3 proven on resection.

MACROSCOPY

A - Cystoprostatectomy specimen with bladder approximately 50 mm in diameter, attached adipose tissue 112 mm x 60 mm. Prostate measuring 35 mm supero-inferiorly x 45 mm lateral x 28 mm anterior-posterior. Opened for research sampling.

The right side of the bladder has an indurated and ulcerated area measuring 20 mm maximum with associated pale firm tumour extending into adjacent adipose tissue and coming close to the anterior and right surgical margin (blue ink). Elsewhere bladder mucosa appears normal.

The prostate shows a minor degree of nodular hyperplasia.

Blocks: A1 = urthra RM; A2 = left side prostate; A4,5,6 & 7 = composite slices of tumour; A8 = tumour; A9 & A10 = right side bladder (composite); A11 = apex; A12 = anterior and left; A13 = bladder neck.

B - Adipose tissue 60 mm, containing ? 3 LNs. Two of them are dense and white with tumour, max size 9 mm.
1 LN per cassette.

C - Two pieces of adipose tissue, together measuring 65 mm, containing a LN.

Blocks: C1 & C2 = 1 LN.

[page 2 of 3]
D - Fatty tissue measuring 40 mm, containing 1 large and 1 small LN.
Blocks: D1 = small LN; D2 & D3 & D4 = large LN.

E - Fatty tissue measuring 60 mm, containing ? 2 LNs.

F - Fatty tissue measuring 50 mm, containing 2 LNs.
Blocks: F1 = 1 LN; F2 & F3 = 1 LN.

G - Fatty tissue measuring 60 mm, containing 2 LNs.

H - Fatty tissue measuring 40 mm, containing 2 LNs.

I - 5 mm length of ureter.

J - 9 mm length of ureter.

MICROSCOPY

A - Bladder and prostate: Sections from the macroscopically identified lesion confirm a poorly differentiated predominantly solid urothelial carcinoma extending with discohesive clusters the entire thickness of the bladder wall into the perivesical fat. The tumour extends to less than 1 mm of the circumferential surgical resection margin on the right side which is composed of compressed soft tissue. There is no lymphocytic infiltrate at the tumour host interface.

Sections away from the main tumour mass contain foreign body-type multinucleated giant cell aggregates in the lamina propria indicative of site of previous biopsy.

Lymphovascular invasion is noted.

There is no perineural invasion.

The adjacent urothelium does not show evidence of dysplasia or carcinoma in situ. There is tumour and ulceration.

Sections of the prostate confirm high grade PIN but there is no evidence of microacinar adenocarcinoma. Some of the acinar structures contain a chronic inflammatory cell infiltrate with an occasional giant cell and is most likely to represent reaction to BCG. The urothelium included does not show any evidence of dysplasia, carcinoma in situ or a papillary urothelial carcinoma.

The urethral surgical margin is within morphologically normal limits.

B - Peri-bladder nodes: Two lymph nodes, both with metastatic urothelial carcinoma. One node shows extracapsular extension.

C - Right external iliac node: One lymph node without metastatic

[page 3 of 3]
carcinoma.

D - Right anterior obturator nodes: Two lymph nodes with florid sinus hyperplasia. No metastatic carcinoma.

E - Right posterior obturator nodes: Two nodes without metastatic carcinoma.

F - Left external iliac nodes: Two lymph nodes with sinus hyperplasia. No metastatic carcinoma.

G - Left anterior obturator nodes: Two lymph nodes with no metastatic carcinoma.

H - Left posterior obturator nodes: Two lymph nodes with no metastatic carcinoma.

I - Left ureteric margin: This is morphologically normal ureter.

J - Right ureteric margin: This is morphologically normal ureter.

SUMMARY (Parts A - J)

Poorly differentiated ulcerated urothelial carcinoma pT3b pN1 R0 (but close circumferential margin on the right side).

Source: NCI Genomic Data Commons file 18c54d4b-a66d-4516-b421-409b5bdb6a0d (TCGA-ZF-A9R1.D0951273-E0D2-4B6F-8033-4745A2AAD74E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).